Somatic mutation profile of tumor specimen C3N-01415-01 (aliquot CPT0105630009) from CPTAC case C3N-01415, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 71.2 years (26,008 days).
Specimen C3N-01415-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b29b8b14-3d24-4bd4-98dc-06a5b419f792.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01415-31 (Blood Derived Normal), aliquot CPT0108100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ca08d32-4d28-4cfc-aaae-cafad31bb5ce

The open-access MAF lists 673 somatic variants for this specimen: 473 protein-altering or splice-affecting, 131 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 405, Silent 131, Intron 35, Nonsense Mutation 22, Frame Shift Del 17, Splice Site 12, 3'UTR 10, Splice Region 10, 5'Flank 7, 5'UTR 6, RNA 6, 3'Flank 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 39/273 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAAS | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 62/807 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.204); catalogued as COSV99266974, COSV99267067; called by muse, mutect2
- ABCA6 | c.4445G>T p.R1482L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99445407; called by muse, mutect2, varscan2
- ABCB5 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 25/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99329145; called by muse, mutect2
- AC131160.1 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 26/720 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs965446860; called by muse, mutect2
- ACAD9 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 111/455 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781156571, CM153911, COSV58310296; called by muse, mutect2, varscan2
- ACTL9 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100185597, COSV61004846; called by muse, mutect2, varscan2
- ADGRA1 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1453389415; called by muse, mutect2
- ADNP2 | c.950del p.G317Efs*15 | Frame Shift Del (DEL) | VAF 12/119 reads (10%) | catalogued as COSV51537697; called by mutect2, pindel, varscan2
- AMER1 | c.1289C>A p.S430Y | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.77); catalogued as COSV57655475; called by muse, mutect2
- ANLN | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 36/393 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs758181302; called by muse, mutect2
- APLP1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375567499; called by muse, mutect2
- AWAT1 | c.733C>A p.R245S | Missense Mutation (SNP) | VAF 191/368 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV65738218; called by muse, mutect2, varscan2
- BAHCC1 | c.3370G>T p.A1124S | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV57027213; called by muse, mutect2, varscan2
- BFSP2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 70/358 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV100183788; called by muse, mutect2, varscan2
- BTNL9 | c.1399G>T p.D467Y | Missense Mutation (SNP) | VAF 83/602 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59795873; called by muse, mutect2, varscan2
- CACTIN | c.557G>C p.G186A | Missense Mutation (SNP) | VAF 62/385 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50271057; called by muse, mutect2, varscan2
- CATSPER1 | c.729C>A p.H243Q | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV56410526; called by muse, mutect2
- CD164L2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs571660185, COSV100927599; called by muse, mutect2, varscan2
- CD5L | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368389928; called by muse, mutect2, varscan2
- CDH12 | c.373T>A p.Y125N | Missense Mutation (SNP) | VAF 34/672 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101203700; called by muse, mutect2
- CDH17 | c.1713C>G p.F571L | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV50327395; called by muse, mutect2
- CDH9 | c.533T>A p.V178D | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50294359; called by muse, mutect2, varscan2
- CDK12 | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as rs1015352888; called by muse, mutect2
- CFAP410 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs751035924; called by muse, mutect2, varscan2
- CFAP61 | c.2245C>G p.R749G | Missense Mutation (SNP) | VAF 72/380 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55624729; called by muse, mutect2, varscan2
- CHD5 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52419577; called by muse, mutect2
- CNGA4 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs145505130; called by muse, mutect2, varscan2
- CNNM1 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 56/411 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1221124443; called by muse, mutect2, varscan2
- COL1A2 | c.2963G>T p.G988V | Missense Mutation (SNP) | VAF 77/728 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72659315, CM070845; called by mutect2, varscan2
- COL5A2 | c.2761G>T p.G921C | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66410586; called by muse, mutect2, varscan2
- COPS7B | c.730G>C p.A244P | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.035); catalogued as COSV63116195; called by muse, mutect2
- CORIN | c.720C>A p.C240* | Nonsense Mutation (SNP) | VAF 26/263 reads (10%) | catalogued as COSV56685886; called by muse, mutect2
- CRACD | c.3482C>A p.S1161Y | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs749267106; called by muse, mutect2
- CREBBP | c.5440G>T p.G1814W | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747252584, COSV52115923, COSV52120627; called by muse, mutect2
- CSMD2 | c.9143C>T p.A3048V | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.858); catalogued as rs146014963, COSV53875096; called by muse, mutect2, varscan2
- CTNND2 | c.983C>G p.P328R | Missense Mutation (SNP) | VAF 64/487 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1277730178; called by muse, mutect2, varscan2
- CYLC2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100872584; called by muse, mutect2
- CYP11B1 | c.1231G>C p.G411R | Missense Mutation (SNP) | VAF 56/606 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99455070; called by muse, mutect2
- DENND2B | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs149905155; called by muse, mutect2, varscan2
- DGAT2 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV99929646; called by muse, mutect2, varscan2
- DHX9 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV100841242; called by muse, mutect2
- DNAJB1 | c.406A>G p.M136V | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs753013282; called by muse, mutect2, varscan2
- DNAJC4 | c.406C>G p.H136D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV54174439; called by muse, mutect2, varscan2
- E2F1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as rs373587139; called by muse, mutect2
- ELP4 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63356131; called by muse, mutect2, varscan2
- EMILIN1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1356011901; called by muse, mutect2, varscan2
- EMILIN1 | c.1353del p.L452Cfs*5 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | catalogued as COSV53155402; called by mutect2, pindel, varscan2
- EPHA5 | c.679C>G p.R227G | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56639139; called by muse, mutect2, varscan2
- FAM217A | c.61-1G>C p.X21_splice | Splice Site (SNP) | VAF 20/175 reads (11%) | catalogued as COSV51160627; called by muse, mutect2, varscan2
- FAT4 | c.10045C>A p.Q3349K | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.295); catalogued as COSV58677319; called by muse, mutect2, varscan2
- FBN2 | c.8105C>A p.S2702Y | Missense Mutation (SNP) | VAF 125/460 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.58); catalogued as COSV99331382; called by muse, mutect2, varscan2
- FGF10 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 46/686 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52937968; called by muse, mutect2
- FNDC3A | c.1253G>T p.C418F (on ENST00000492622 / NM_001079673.2; = p.C362F on NM_014923.5) | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1353522287; called by muse, mutect2, varscan2
- GALR1 | c.920C>A p.S307Y | Missense Mutation (SNP) | VAF 63/344 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55319825; called by muse, mutect2, varscan2
- IFNA2 | c.188A>T p.Q63L | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs1284620957; called by muse, mutect2, varscan2
- IGSF9 | c.2315G>A p.R772H (on ENST00000368094 / NM_001135050.2; = p.R756H on NM_020789.4) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as rs1340975643, COSV63638825; called by muse, mutect2, varscan2
- ILDR2 | c.1375C>G p.R459G | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV99613594; called by muse, mutect2, varscan2
- IRF4 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs755460615, COSV66705603; called by muse, mutect2, varscan2
- IRF8 | c.556G>T p.V186L | Missense Mutation (SNP) | VAF 49/525 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99236729; called by muse, mutect2
- KAT6B | c.1400A>T p.K467M | Missense Mutation (SNP) | VAF 104/748 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99767215; called by mutect2, varscan2
- KCNA5 | c.812C>A p.T271N | Missense Mutation (SNP) | VAF 60/505 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376951346; called by muse, mutect2, varscan2
- KIAA1143 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56088848; called by muse, mutect2
- KIF26A | c.4447G>A p.G1483S | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs775132075, COSV59465587; called by muse, mutect2, varscan2
- KMT2D | c.6949G>T p.G2317C | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV56495563; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2
- MGAM | c.1892C>A p.A631D | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782592725, COSV72074580; called by muse, mutect2, varscan2
- MRGPRX4 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.187); catalogued as rs1043434232, COSV58590802; called by muse, mutect2
- MTNR1A | c.583C>A p.H195N | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56158096; called by muse, mutect2, varscan2
- MUC17 | c.2245T>A p.L749I | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV60302745; called by muse, mutect2, varscan2
- MYO1F | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 42/580 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156708600; called by muse, mutect2
- NCOA1 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1212938561; called by muse, mutect2, varscan2
- NFE2L3 | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs771810558, COSV50233228; called by muse, mutect2, varscan2
- NID1 | c.2305T>G p.C769G | Missense Mutation (SNP) | VAF 95/351 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs769350405; called by muse, mutect2, varscan2
- NLRP10 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.418); catalogued as rs1186100956, COSV60780770; called by muse, mutect2
- OR14K1 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99315489; called by muse, mutect2, varscan2
- OR2G6 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 53/415 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as COSV100598350; called by muse, mutect2, varscan2
- OR4C6 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as COSV58603134, COSV58603870, COSV58604215; called by muse, mutect2, varscan2
- OR52B2 | c.909G>T p.E303D | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs558250641; called by muse, mutect2, varscan2
- OR52N1 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 79/480 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57692903; called by muse, mutect2, varscan2
- PACSIN1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 151/527 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.403); catalogued as COSV55061413; called by muse, mutect2, varscan2
- PCDHA8 | c.508T>A p.Y170N | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65339531; called by muse, mutect2, varscan2
- PCDHA9 | c.2333C>G p.P778R | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as rs564915131, COSV65333893; called by muse, mutect2, varscan2
- PCDHGA6 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV53938304; called by muse, mutect2, varscan2
- PLA2R1 | c.1405C>A p.H469N | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV51781389; called by muse, mutect2, varscan2
- PLOD2 | c.2155G>T p.E719* | Nonsense Mutation (SNP) | VAF 37/317 reads (12%) | catalogued as COSV51464684; called by muse, mutect2, varscan2
- PNLIP | c.999del p.T335Qfs*10 | Frame Shift Del (DEL) | VAF 26/291 reads (9%) | catalogued as COSV65039555; called by mutect2, pindel
- PROKR2 | c.850T>A p.Y284N | Missense Mutation (SNP) | VAF 74/818 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568569285; called by muse, mutect2
- RAD17 | c.967G>C p.E323Q (on ENST00000380774 / NM_133339.2; = p.E312Q on NM_002873.1) | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV99281171; called by muse, mutect2, varscan2
- REG3A | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100532639; called by muse, mutect2, varscan2
- RELA | c.513G>T p.R171S | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.559); catalogued as rs746111744, COSV58014617; called by muse, mutect2
- RGS7 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 84/624 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1249029275, COSV58547558, COSV58555678; called by muse, mutect2, varscan2
- RIMS2 | c.2465G>T p.R822L (on ENST00000666250 / NM_001348490.2; = p.R630L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766328696, COSV51715648; called by muse, mutect2
- RIMS2 | c.2467G>T p.V823F (on ENST00000666250 / NM_001348490.2; = p.V631F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774233059, COSV51668924; called by muse, mutect2
- RP1L1 | c.1435G>T p.G479W | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV66754487; called by muse, mutect2, varscan2
- RSRC1 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV55837001; called by muse, varscan2
- RUNX1T1 | c.890C>T p.P297L (on ENST00000265814 / NM_001198628.1; = p.P270L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/418 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99749604; called by muse, mutect2
- SCNN1B | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 173/812 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as rs756809433, COSV56303330; called by muse, mutect2, varscan2
- SEC16B | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs768623007, COSV100381797; called by muse, mutect2, varscan2
- SETBP1 | c.3298C>A p.H1100N | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV56313850, COSV56329482, COSV99953805; called by muse, mutect2, varscan2
- SIDT2 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV54059583; called by muse, mutect2, varscan2
- SLC5A6 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100143422; called by muse, mutect2, varscan2
- SND1 | c.2554G>A p.G852R | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61238179; called by muse, mutect2, varscan2
- SOX7 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1249702262, COSV100449013; called by muse, mutect2, varscan2
- SPATA31A6 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs1249262859; called by mutect2, varscan2
- SPOCK3 | c.596G>T p.R199I | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100694263; called by muse, varscan2
- SPTA1 | c.5731C>A p.P1911T | Missense Mutation (SNP) | VAF 123/524 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV100934660; called by muse, mutect2, varscan2
- SRM | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 29/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747238597; called by muse, mutect2
- SRPRA | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1375595284; called by muse, mutect2, varscan2
- SYP | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1557102718; called by muse, mutect2
- TGM5 | c.1229G>A p.G410E (on ENST00000220420 / NM_201631.4; = p.G328E on NM_004245.4) | Missense Mutation (SNP) | VAF 62/654 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1324725373; called by muse, mutect2
- TIMM21 | c.571_572del p.T191Vfs*7 | Frame Shift Del (DEL) | VAF 27/240 reads (11%) | catalogued as rs1474894332; called by pindel, varscan2
- TLL2 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553324585; called by muse, mutect2, varscan2
- TMEM174 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99703695; called by muse, mutect2, varscan2
- TMEM65 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs779556138, COSV52629536; called by muse, mutect2
- TNS3 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 159/544 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs144374552; called by muse, mutect2, varscan2
- TRPC7 | c.2575G>A p.G859S | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV61464503; called by muse, mutect2, varscan2
- TRPS1 | c.2270G>C p.G757A (on ENST00000220888 / NM_001330599.2; = p.G770A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/792 reads (6%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.293); catalogued as COSV55240280; called by muse, mutect2
- TRRAP | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV62849051, COSV62851611; called by muse, mutect2
- TSHZ2 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61586704, COSV61591051; called by muse, mutect2, varscan2
- TTN | c.15720G>T p.K5240N (on ENST00000591111; = p.K4313N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | PolyPhen benign (0.003); catalogued as COSV60417965; called by muse, mutect2, varscan2
- UBQLN3 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs999501348, COSV61165114; called by muse, mutect2, varscan2
- WASHC2A | c.163A>G p.I55V | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs538396835; called by muse, mutect2, varscan2
- WDR72 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774365556; called by muse, mutect2, varscan2
- XYLT1 | c.1807G>T p.V603L | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as COSV54495700; called by muse, mutect2
- ZBP1 | c.35-1G>T p.X12_splice | Splice Site (SNP) | VAF 52/204 reads (25%) | catalogued as rs746443685; called by muse, varscan2
- ZNF275 | c.1079G>T p.G360V (on ENST00000650114 / NM_001367757.1; = p.W327C on NM_001080485.3) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.535); catalogued as COSV64705225; called by muse, mutect2, varscan2
- ZNF276 | c.1451G>A p.R484H (on ENST00000443381 / NM_001113525.2; = p.R409H on NM_152287.4) | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1395828475, COSV57072256; called by muse, mutect2, varscan2
- ZNF479 | c.995A>G p.K332R | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV58637676; called by muse, mutect2, varscan2
- ZNF543 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV58628505; called by muse, mutect2, varscan2
- ZNF560 | c.2141G>A p.C714Y | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775645027; called by muse, mutect2
- ZNF606 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100357361; called by muse, mutect2
- ZNF808 | c.-18A>G | Splice Region (SNP) | VAF 21/111 reads (19%) | catalogued as rs770372288, COSV100707869; called by muse, mutect2, varscan2
- ZNF85 | c.865A>G p.K289E | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs775582693, COSV60214420; called by muse, mutect2, varscan2
- ZSCAN1 | c.132C>A p.F44L | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568601275; called by muse, mutect2
- ABCA13 | c.4908G>T p.R1636S | Missense Mutation (SNP) | VAF 174/670 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ABCA6 | c.4648G>T p.V1550L | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AC004922.1 | c.1985G>T p.R662I | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AC068643.2 | n.556-1G>T | Splice Site (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- ACADSB | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 75/471 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ACVRL1 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 88/434 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ADAMTS12 | c.4742G>C p.R1581T | Missense Mutation (SNP) | VAF 29/492 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2
- ADAMTS2 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); called by muse, varscan2
- ADGRL4 | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK | c.2234G>T p.W745L | Missense Mutation (SNP) | VAF 92/404 reads (23%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ALDH1L1 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ANK1 | c.754G>C p.V252L | Missense Mutation (SNP) | VAF 103/536 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ANKRD31 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- ANO6 | c.390G>T p.W130C | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- APCS | c.578A>T p.Q193L | Missense Mutation (SNP) | VAF 83/286 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF35 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 56/180 reads (31%) | called by mutect2, varscan2
- ARL15 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 111/267 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB5 | c.430T>A p.C144S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- BARHL2 | c.317A>C p.Q106P | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- BCL9 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BNC2 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BRWD3 | c.5115G>C p.R1705S | Missense Mutation (SNP) | VAF 149/283 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- C10orf71 | c.3937C>A p.P1313T | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C3 | c.3574G>T p.A1192S | Missense Mutation (SNP) | VAF 78/505 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- C5orf47 | c.367A>T p.I123L | Missense Mutation (SNP) | VAF 111/326 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CAPNS1 | c.575G>T p.S192I | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.59); called by muse, mutect2
- CASS4 | c.1858G>T p.E620* | Nonsense Mutation (SNP) | VAF 28/362 reads (8%) | called by muse, mutect2
- CCDC171 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC80 | c.2315T>C p.L772P | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CCNJL | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- CD163L1 | c.4027G>C p.V1343L | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- CD1D | c.147G>C p.W49C | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CD22 | c.1741G>T p.A581S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD2BP2 | c.441G>C p.L147F | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.154); called by muse, mutect2
- CDC14C | c.503C>A p.P168Q (on ENST00000428251; = p.P61Q on NM_152627.3) | Missense Mutation (SNP) | VAF 80/455 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH22 | c.2002A>G p.I668V | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.063); called by muse, mutect2
- CDK20 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CEP350 | c.6798G>C p.L2266F | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CFAP20DC | c.1035G>T p.M345I (on ENST00000482387 / NM_001351530.2; = p.M220I on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, varscan2
- CFAP54 | c.7257A>T p.E2419D | Missense Mutation (SNP) | VAF 76/332 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- CHRNB2 | c.528G>C p.W176C | Missense Mutation (SNP) | VAF 77/644 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CILP2 | c.2410G>T p.A804S | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CKAP4 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CLPTM1L | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CLSTN2 | c.129G>A p.W43* | Nonsense Mutation (SNP) | VAF 27/153 reads (18%) | called by muse, mutect2, varscan2
- CNOT10 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CNTN4 | c.2489G>T p.R830I | Missense Mutation (SNP) | VAF 55/417 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- CNTN4 | c.2490A>T p.R830S | Missense Mutation (SNP) | VAF 53/423 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL11A1 | c.3276T>A p.P1092= | Splice Region (SNP) | VAF 94/427 reads (22%) | called by muse, mutect2, varscan2
- COL3A1 | c.880G>T p.G294* | Nonsense Mutation (SNP) | VAF 48/275 reads (17%) | called by muse, mutect2, varscan2
- COL5A2 | c.2762G>T p.G921V | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A5 | c.7061C>A p.P2354H (on ENST00000312481; = p.P2350H on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/497 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- COL9A3 | c.955-1G>T p.X319_splice | Splice Site (SNP) | VAF 39/380 reads (10%) | called by muse, mutect2, varscan2
- CPA2 | c.1226C>G p.A409G | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- CPEB2 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- CPNE5 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 30/387 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- CREBBP | c.3692A>T p.Q1231L | Missense Mutation (SNP) | VAF 23/578 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- CWC22 | c.753A>G p.Q251= | Splice Region (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- CYLC1 | c.1496C>G p.S499* | Nonsense Mutation (SNP) | VAF 109/204 reads (53%) | called by muse, mutect2, varscan2
- CYLC1 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- CYP2C8 | c.910A>G p.T304A | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.207); called by muse, mutect2
- CYP4F3 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 65/389 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- D2HGDH | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 49/361 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DDX19B | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DEPDC5 | c.2760G>C p.R920S (on ENST00000400246; = p.R989S on NM_014662.5) | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DES | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- DHX58 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DKK4 | c.28A>T p.S10C | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- DLG1 | c.813G>T p.R271= | Splice Region (SNP) | VAF 28/128 reads (22%) | called by muse, mutect2
- DLL3 | c.1267G>A p.G423S | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- DLL3 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DLST | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); called by muse, mutect2
- DMRTC2 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DNAH8 | c.7286T>C p.L2429S | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAI2 | c.813G>T p.W271C | Missense Mutation (SNP) | VAF 77/491 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAJC1 | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 69/372 reads (19%) | called by muse, mutect2, varscan2
- DOP1B | c.2968G>T p.G990W | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DPP4 | c.1117A>C p.K373Q | Missense Mutation (SNP) | VAF 15/267 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.729); called by muse, mutect2
- DPRX | c.238C>G p.H80D | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPY19L2 | c.2001G>A p.R667= | Splice Region (SNP) | VAF 29/153 reads (19%) | called by muse, mutect2, varscan2
- DPYD | c.719T>A p.V240E | Missense Mutation (SNP) | VAF 59/472 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DRD5 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSCAM | c.5827C>G p.L1943V | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DSP | c.2903A>G p.Y968C | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DST | c.219A>T p.L73F | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DTNA | c.1508C>A p.P503H | Missense Mutation (SNP) | VAF 59/559 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF2K | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.076); called by muse, mutect2
- EPOR | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.184); called by muse, mutect2
- ESPNL | c.1826G>T p.G609V | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- F5 | c.4698C>A p.N1566K | Missense Mutation (SNP) | VAF 67/382 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FAHD2B | c.522G>T p.K174N | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.529); called by muse, mutect2
- FAM114A2 | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAT4 | c.4609G>T p.A1537S | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- FBLN1 | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN2 | c.6257del p.G2086Afs*163 | Frame Shift Del (DEL) | VAF 36/354 reads (10%) | called by mutect2, pindel
- FBXL7 | c.317G>T p.R106I | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXL7 | c.1255G>T p.G419C | Missense Mutation (SNP) | VAF 75/567 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXO45 | c.857G>C p.G286A | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FGF18 | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 50/674 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.861); called by muse, mutect2
- FIP1L1 | c.558del p.A187Lfs*18 | Frame Shift Del (DEL) | VAF 16/159 reads (10%) | called by mutect2, pindel, varscan2
- FLNC | c.4958G>T p.C1653F | Missense Mutation (SNP) | VAF 93/482 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- FOXG1 | c.424C>G p.P142A | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- FOXR1 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, varscan2
- FPGT | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAB4 | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- GAS2 | c.684A>T p.Q228H | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- GBA3 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 16/361 reads (4%) | called by muse, mutect2
- GCC2 | c.63+6G>C | Splice Region (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- GDAP2 | c.29T>C p.F10S | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- GIMAP7 | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GJD2 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 54/613 reads (9%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- GOLT1B | c.118G>C p.V40L | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR150 | c.1241G>A p.G414D | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- GPR153 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- GPR65 | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); called by muse, mutect2
- GUSB | c.1472A>T p.K491M | Missense Mutation (SNP) | VAF 41/545 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.098); called by muse, mutect2
- H2AC8 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.095); called by muse, mutect2
- H2AW | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2
- H2BC21 | c.368C>A p.T123N | Missense Mutation (SNP) | VAF 77/580 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- H3C11 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 27/283 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); called by muse, mutect2
- HEPACAM | c.1109C>A p.A370D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.115); called by muse, mutect2
- HMX1 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- HS3ST3A1 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 23/293 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, varscan2
- IFNAR2 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- IFT122 | c.2396A>G p.K799R (on ENST00000348417 / NM_052989.3; = p.K740R on NM_018262.4) | Missense Mutation (SNP) | VAF 147/612 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IFT140 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); called by muse, mutect2
- IGKV1-12 | c.83A>T p.Q28L | Missense Mutation (SNP) | VAF 38/861 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- IGLV5-37 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 40/397 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IL1R1 | c.1605G>T p.R535S | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL1RL1 | c.1170T>A p.S390R | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ILVBL | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- IMMT | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- INAFM1 | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INPP5D | c.965C>G p.S322C (on ENST00000445964 / NM_001017915.3; = p.S321C on NM_005541.5) | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- INSM2 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by mutect2, varscan2
- INSR | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITGA2 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 57/928 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITPR3 | c.6670C>T p.P2224S | Missense Mutation (SNP) | VAF 27/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JAKMIP1 | c.2163C>A p.D721E | Missense Mutation (SNP) | VAF 52/560 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2
- JCAD | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 82/452 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KBTBD6 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KCNN2 | c.1079G>A p.G360D (on ENST00000264773; = p.G572D on NM_021614.4) | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNN2 | c.1682C>G p.S561W (on ENST00000264773; = p.S773W on NM_021614.4) | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- KDM5A | c.133_142del p.K45Sfs*18 | Frame Shift Del (DEL) | VAF 36/430 reads (8%) | called by mutect2, pindel
- KIAA1109 | c.14102G>T p.G4701V | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIAA1217 | c.5314G>T p.D1772Y | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF26A | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 162/652 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by mutect2, varscan2
- KIF26A | c.2516G>T p.S839I | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2
- KLK1 | c.90G>T p.E30D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2
- KLK7 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2D | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- LAIR1 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA2 | c.2601C>G p.C867W | Missense Mutation (SNP) | VAF 54/535 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAMA4 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 55/485 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LARP4B | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LCT | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 76/466 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- LGALS4 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LIPK | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIPN | c.967C>A p.H323N | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, varscan2
- LIPT2 | c.466+8C>G | Splice Region (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2
- LRIT1 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.662); called by muse, varscan2
- LRRC27 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- LRRC4B | c.7C>A p.R3S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LSP1 | c.1013C>A p.A338D | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MME | c.2087G>T p.G696V | Missense Mutation (SNP) | VAF 154/605 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MMEL1 | c.2038G>T p.D680Y | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MON1A | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.283); called by muse, mutect2
- MROH1 | c.4873_4900del p.E1625Wfs*5 | Frame Shift Del (DEL) | VAF 157/586 reads (27%) | called by mutect2, pindel
- MROH2A | c.4772T>A p.L1591Q | Missense Mutation (SNP) | VAF 21/349 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2
- MROH7 | c.830A>T p.N277I | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- MTHFD1L | c.2876G>T p.R959L | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- MTNR1A | c.584A>C p.H195P | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- MTPN | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MTR | c.882dup p.G295Wfs*2 | Frame Shift Ins (INS) | VAF 52/508 reads (10%) | called by mutect2, pindel
- MTTP | c.2144C>A p.S715Y | Missense Mutation (SNP) | VAF 98/527 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MUC17 | c.13451A>C p.Q4484P | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- MXD4 | c.308A>T p.K103M | Missense Mutation (SNP) | VAF 31/357 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MYLK4 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MYO18B | c.5086A>C p.S1696R | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MYO1F | c.193T>A p.Y65N | Missense Mutation (SNP) | VAF 46/530 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- NAA25 | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 69/330 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NASP | c.562A>T p.I188L | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOA3 | c.3589A>T p.N1197Y | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NDNF | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- NDRG1 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 22/733 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- NEDD4 | c.2071G>A p.D691N (on ENST00000508342 / NM_001284338.1; = p.D272N on NM_006154.4) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- NEK1 | c.3700G>A p.E1234K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- NGEF | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- NGEF | c.1131T>A p.Y377* | Nonsense Mutation (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- NGEF | c.738C>A p.H246Q | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NLGN3 | c.1181G>T p.G394V (on ENST00000358741 / NM_181303.2; = p.G374V on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- NPEPL1 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NT5C1B | c.554T>A p.L185Q (on ENST00000359846 / NM_001199086.2; = p.L125Q on NM_033253.4) | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTRK2 | c.2464G>T p.G822C (on ENST00000323115 / NM_001369534.1; = p.G838C on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/482 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR10C1 | c.124G>T p.G42C (on ENST00000622521; = p.G40C on NM_013941.3) | Missense Mutation (SNP) | VAF 70/446 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR10Q1 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- OR2D2 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.639); called by muse, mutect2
- OR2H2 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.038); called by muse, mutect2
- OR2M3 | c.921G>T p.K307N | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.036); called by muse, mutect2
- OR52M1 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5C1 | c.766T>A p.Y256N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5C1 | c.767A>C p.Y256S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5H14 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 60/487 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR6C3 | c.346T>C p.S116P | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- OR6P1 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OR8H1 | c.364T>A p.Y122N | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OR8I2 | c.406A>T p.M136L | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- OR8J3 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OSBPL5 | c.1246del p.A416Lfs*11 | Frame Shift Del (DEL) | VAF 14/139 reads (10%) | called by mutect2, pindel
- P2RY1 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 46/332 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PAPOLA | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PARP14 | c.4982A>T p.Q1661L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAX1 | c.1028C>A p.P343H | Missense Mutation (SNP) | VAF 164/744 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PCDHGB2 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- PCLO | c.6188C>G p.A2063G | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- PDE4A | c.562_570del p.L188_S190del | In Frame Del (DEL) | VAF 32/290 reads (11%) | called by mutect2, pindel
- PDE6B | c.609C>G p.S203R | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- PEX6 | c.2111G>T p.W704L | Missense Mutation (SNP) | VAF 178/724 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGAM2 | c.535_538del p.K179Efs*29 | Frame Shift Del (DEL) | VAF 39/253 reads (15%) | called by mutect2, pindel, varscan2
- PHKA1 | c.3575C>G p.A1192G | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIK3R2 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | called by muse, varscan2
- PIK3R3 | c.216G>T p.R72S | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- PKD2 | c.2630G>C p.R877T | Missense Mutation (SNP) | VAF 81/438 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PKHD1 | c.6997-2A>T p.X2333_splice | Splice Site (SNP) | VAF 126/531 reads (24%) | called by muse, mutect2, varscan2
- PKP4 | c.210G>C p.R70S | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- PLEKHM1 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 103/388 reads (27%) | called by muse, mutect2, varscan2
- PLPPR5 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 36/363 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLXNB2 | c.4552C>T p.R1518C | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POC1B | c.173del p.G58Vfs*6 | Frame Shift Del (DEL) | VAF 41/251 reads (16%) | called by mutect2, pindel, varscan2
- POM121L2 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 14/309 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- POTEI | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, varscan2
- PPARD | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 39/248 reads (16%) | called by muse, mutect2, varscan2
- PPP2R5A | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRAMEF17 | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 143/680 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PRIM2 | c.368A>T p.Q123L | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- PRKX | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROC | c.381_382insCTCCC p.G128Lfs*10 | Frame Shift Ins (INS) | VAF 27/143 reads (19%) | called by mutect2, pindel, varscan2
- PSMB2 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMB3 | c.243G>C p.Q81H | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTN | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPN13 | c.3755A>C p.E1252A (on ENST00000411767 / NM_080683.3; = p.E1233A on NM_006264.3) | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- PYHIN1 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- QDPR | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- RAG1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 44/469 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- RAG1 | c.2179G>T p.V727F | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); called by muse, varscan2
- RALGAPA2 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- RBM33 | c.3376-1G>T p.X1126_splice | Splice Site (SNP) | VAF 47/227 reads (21%) | called by muse, mutect2, varscan2
- RBMXL2 | c.565G>C p.G189R | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, varscan2
- RHBDD2 | c.1095A>C p.*365Cext*4 | Nonstop Mutation (SNP) | VAF 31/132 reads (23%) | called by muse, mutect2, varscan2
- RNF17 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); called by muse, mutect2
- RNF180 | c.180G>T p.W60C | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RPH3A | c.332C>T p.A111V (on ENST00000389385 / NM_001143854.2; = p.A107V on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, varscan2
- SDE2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA3A | c.647A>C p.H216P | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- SERPINB11 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- SERTAD4 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SIM1 | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.325); called by muse, mutect2
- SLC35F5 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 85/349 reads (24%) | called by muse, mutect2, varscan2
- SLC35G2 | c.584_588del p.T195Nfs*20 | Frame Shift Del (DEL) | VAF 64/554 reads (12%) | called by mutect2, pindel
- SLC5A5 | c.1222C>A p.L408I | Missense Mutation (SNP) | VAF 72/574 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SLCO1B1 | c.1748-2A>T p.X583_splice | Splice Site (SNP) | VAF 46/285 reads (16%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.1073del p.G358Afs*14 | Frame Shift Del (DEL) | VAF 37/172 reads (22%) | called by mutect2, pindel, varscan2
- SMCO2 | c.738T>A p.S246R | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2
- SMG1 | c.326G>T p.R109M | Missense Mutation (SNP) | VAF 134/677 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- SNAPC4 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, varscan2
- SNRNP200 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 178/602 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SNRPC | c.177A>T p.Q59H | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- SPATA31A3 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 130/1230 reads (11%) | called by muse, mutect2, varscan2
- SPEG | c.2821A>G p.T941A | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SPICE1 | c.1658-1G>C p.X553_splice | Splice Site (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- SPTY2D1 | c.1745A>G p.K582R | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- SRPK3 | c.60-8A>T | Splice Region (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- SSTR5 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 146/793 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSU72 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2, varscan2
- STAT5B | c.1568G>T p.R523L | Missense Mutation (SNP) | VAF 109/684 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- STRA6 | c.1476G>T p.W492C | Missense Mutation (SNP) | VAF 64/570 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, varscan2
- STRC | c.4916T>G p.L1639R | Missense Mutation (SNP) | VAF 50/445 reads (11%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- STXBP1 | c.658G>T p.G220W | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP1 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 85/369 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUGCT | c.1072G>T p.V358L | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2
- SYCP2L | c.1071A>T p.T357= | Splice Region (SNP) | VAF 18/253 reads (7%) | called by muse, mutect2
- TBC1D10C | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.053); called by muse, mutect2
- TBC1D9 | c.250A>G p.R84G | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- TDRD9 | c.3932G>T p.R1311I | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- TDRKH | c.605_607delinsGG p.K202Rfs*19 | Frame Shift Del (DEL) | VAF 28/260 reads (11%) | called by pindel, varscan2*
- TEKT4 | c.858C>A p.D286E | Missense Mutation (SNP) | VAF 73/303 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- TENM2 | c.4457G>T p.G1486V (on ENST00000518659 / NM_001122679.2; = p.G1247V on NM_001080428.3) | Missense Mutation (SNP) | VAF 112/389 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TEP1 | c.7666G>T p.G2556C | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TEX30 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TFF2 | c.377-1G>T p.X126_splice | Splice Site (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- TGM5 | c.1499G>T p.R500L (on ENST00000220420 / NM_201631.4; = p.R418L on NM_004245.4) | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by muse, varscan2
- TICRR | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 33/302 reads (11%) | called by muse, mutect2, varscan2
- TM9SF4 | c.1441G>T p.V481L | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- TMEM171 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.038); called by muse, varscan2
- TMPO | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 59/510 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TMTC1 | c.2328G>T p.K776N (on ENST00000539277 / NM_001193451.2; = p.K668N on NM_175861.3) | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TNIK | c.2948A>G p.Q983R | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2
- TNN | c.1141T>A p.Y381N | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- TNN | c.3514T>A p.Y1172N | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- TRAK1 | c.2543G>T p.R848M | Missense Mutation (SNP) | VAF 69/372 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- TRAPPC11 | c.2695-2A>T p.X899_splice | Splice Site (SNP) | VAF 25/125 reads (20%) | called by muse, mutect2, varscan2
- TRBV28 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TREM1 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIL | c.1877G>T p.R626L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- TRIM23 | c.1691A>G p.Q564R | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- TRIML1 | c.671G>T p.S224I | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TRPM5 | c.668del p.I223Tfs*29 | Frame Shift Del (DEL) | VAF 16/208 reads (8%) | called by mutect2, pindel
- TRPM6 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 100/464 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2
- TRPM6 | c.790A>G p.K264E | Missense Mutation (SNP) | VAF 102/466 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2
- TRPV6 | c.1174C>A p.L392I | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TSNARE1 | c.1131+1G>T p.X377_splice | Splice Site (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- TTC7B | c.1967-1G>T p.X656_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.61239C>A p.D20413E (on ENST00000591111; = p.D12989E on NM_003319.4) | Missense Mutation (SNP) | VAF 24/293 reads (8%) | PolyPhen possibly damaging (0.475); called by muse, mutect2
- UEVLD | c.46A>T p.K16* | Nonsense Mutation (SNP) | VAF 33/241 reads (14%) | called by muse, mutect2, varscan2
- UMOD | c.1664T>G p.F555C | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USH2A | c.95A>T p.E32V | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VN1R4 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 54/450 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- VSTM2A | c.498G>T p.W166C | Missense Mutation (SNP) | VAF 101/483 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VWA3B | c.3071C>A p.T1024K | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WAS | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- WASHC4 | c.60G>A p.Q20= | Splice Region (SNP) | VAF 24/280 reads (9%) | called by muse, mutect2
- WNT5A | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, varscan2
- ZBED9 | c.2569G>T p.G857C | Missense Mutation (SNP) | VAF 160/657 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDBF2 | c.4760A>G p.K1587R | Missense Mutation (SNP) | VAF 23/273 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.083); called by muse, mutect2
- ZNF106 | c.3489_3490insAG p.S1165Lfs*15 | Frame Shift Ins (INS) | VAF 34/356 reads (10%) | called by mutect2, pindel
- ZNF236 | c.1331A>T p.Q444L | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF335 | c.2642A>G p.Y881C | Missense Mutation (SNP) | VAF 92/376 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF33B | c.1390A>C p.T464P | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF385B | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF420 | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF469 | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 48/491 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ZNF519 | c.1330G>T p.G444C | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ZNF541 | c.2136del p.L713Cfs*63 | Frame Shift Del (DEL) | VAF 29/273 reads (11%) | called by mutect2, pindel
- ZNF574 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF597 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 18/293 reads (6%) | called by muse, mutect2
- ZNF775 | c.647A>G p.D216G | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- ZNRF4 | c.146del p.P49Qfs*21 | Frame Shift Del (DEL) | VAF 35/227 reads (15%) | called by mutect2, pindel, varscan2
- ADAM11 | c.1923G>A p.A641= | Silent (SNP) | VAF 13/222 reads (6%) | catalogued as rs1186095089; called by muse, mutect2
- ADAM29 | c.414C>A p.P138= | Silent (SNP) | VAF 30/202 reads (15%) | called by muse, mutect2, varscan2
- ADGRA3 | c.3381C>T p.A1127= | Silent (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- AHNAK2 | c.8919C>T p.A2973= | Silent (SNP) | VAF 56/700 reads (8%) | called by muse, mutect2
- ALDH16A1 | c.1746C>T p.G582= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- AMER1 | c.1290C>T p.S430= | Silent (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- AMPD3 | c.1188G>T p.V396= (on ENST00000396553 / NM_001025389.2; = p.V405= on NM_000480.3) | Silent (SNP) | VAF 146/579 reads (25%) | called by muse, mutect2, varscan2
- ANGPTL7 | c.120C>A p.L40= | Silent (SNP) | VAF 20/370 reads (5%) | catalogued as rs1483505432; called by muse, mutect2
- ANK1 | c.2226C>T p.A742= | Silent (SNP) | VAF 60/605 reads (10%) | catalogued as COSV55897549; called by muse, mutect2, varscan2
- ANO3 | c.96G>A p.P32= | Silent (SNP) | VAF 23/268 reads (9%) | catalogued as rs780379245, COSV99882791; called by muse, mutect2
- ARFGEF3 | c.6432G>T p.P2144= | Silent (SNP) | VAF 61/191 reads (32%) | catalogued as rs756476305; called by muse, mutect2, varscan2
- ATP11C | c.114C>T p.Y38= | Silent (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- C5orf47 | c.141A>T p.A47= | Silent (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.1986G>C p.L662= | Silent (SNP) | VAF 34/169 reads (20%) | called by muse, mutect2, varscan2
- CARD14 | c.1947C>T p.F649= | Silent (SNP) | VAF 31/197 reads (16%) | catalogued as COSV60126168; called by muse, mutect2
- CCN3 | c.444G>T p.V148= | Silent (SNP) | VAF 28/424 reads (7%) | called by muse, mutect2
- CDH12 | c.1839C>T p.S613= | Silent (SNP) | VAF 20/390 reads (5%) | called by muse, mutect2
- COL16A1 | c.1632C>G p.G544= | Silent (SNP) | VAF 58/272 reads (21%) | called by muse, mutect2, varscan2
- CTNND2 | c.984G>A p.P328= | Silent (SNP) | VAF 64/482 reads (13%) | called by muse, mutect2, varscan2
- CUL7 | c.801G>A p.L267= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as rs1387883971; called by muse, mutect2, varscan2
- CYP4F3 | c.169C>A p.R57= | Silent (SNP) | VAF 79/341 reads (23%) | called by muse, mutect2, varscan2
- DAPK3 | c.120A>T p.A40= | Silent (SNP) | VAF 34/201 reads (17%) | called by muse, mutect2, varscan2
- DLG5 | c.4587G>C p.V1529= | Silent (SNP) | VAF 37/241 reads (15%) | called by muse, mutect2, varscan2
- DTNA | c.1509C>A p.P503= | Silent (SNP) | VAF 62/564 reads (11%) | called by muse, mutect2, varscan2
- EGFR | c.3453C>T p.F1151= | Silent (SNP) | VAF 43/716 reads (6%) | catalogued as rs1040652650, COSV51766010, COSV99289543; called by muse, mutect2
- ELMO1 | c.1702C>A p.R568= | Silent (SNP) | VAF 36/244 reads (15%) | catalogued as COSV60294080; called by muse, mutect2, varscan2
- EPYC | c.562C>A p.R188= | Silent (SNP) | VAF 67/287 reads (23%) | catalogued as CM142384; called by muse, mutect2, varscan2
- EVPL | c.4047C>T p.D1349= | Silent (SNP) | VAF 20/224 reads (9%) | catalogued as rs773564916; called by muse, mutect2
- EVPL | c.1407A>T p.A469= | Silent (SNP) | VAF 78/270 reads (29%) | called by muse, mutect2, varscan2
- EXTL3 | c.1284C>T p.S428= | Silent (SNP) | VAF 49/307 reads (16%) | called by muse, mutect2, varscan2
- EZHIP | c.222C>T p.S74= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs1325333689; called by muse, mutect2, varscan2
- FAM47B | c.756C>T p.P252= | Silent (SNP) | VAF 64/184 reads (35%) | catalogued as rs775653720, COSV100264534; called by muse, mutect2, varscan2
- FBXL7 | c.1254G>C p.T418= | Silent (SNP) | VAF 76/574 reads (13%) | catalogued as COSV100310440; called by muse, mutect2, varscan2
- FGD3 | c.570G>A p.A190= | Silent (SNP) | VAF 57/192 reads (30%) | catalogued as rs1424997534; called by muse, mutect2, varscan2
- FGD5 | c.2316A>G p.S772= | Silent (SNP) | VAF 33/181 reads (18%) | called by muse, mutect2, varscan2
- FRMPD4 | c.3012T>A p.T1004= | Silent (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- GABRG2 | c.1158C>A p.V386= (on ENST00000361925 / NM_001375343.1; = p.V346= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/1066 reads (3%) | called by muse, mutect2
- GAL3ST3 | c.1236C>A p.V412= | Silent (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- GLIS1 | c.816C>A p.A272= | Silent (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- GP9 | c.468C>A p.A156= | Silent (SNP) | VAF 24/212 reads (11%) | catalogued as rs1031961498; called by muse, mutect2, varscan2
- HGF | c.1480C>A p.R494= | Silent (SNP) | VAF 70/412 reads (17%) | catalogued as rs1038654267, COSV55956894; called by muse, mutect2, varscan2
- IGLC7 | c.220C>T p.L74= | Silent (SNP) | VAF 190/853 reads (22%) | catalogued as rs1416414786; called by muse, mutect2, varscan2
- IL12RB1 | c.1065C>T p.T355= | Silent (SNP) | VAF 26/288 reads (9%) | called by muse, mutect2
- IMPACT | c.309C>T p.Y103= | Silent (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- INSYN2A | c.291C>T p.P97= | Silent (SNP) | VAF 22/351 reads (6%) | called by muse, mutect2
- IRX1 | c.1431C>G p.L477= | Silent (SNP) | VAF 39/673 reads (6%) | called by muse, mutect2
- KCNB1 | c.207G>T p.L69= | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as COSV100870448; called by muse, mutect2, varscan2
- KCNN2 | c.1683G>T p.S561= (on ENST00000264773; = p.S773= on NM_021614.4) | Silent (SNP) | VAF 41/243 reads (17%) | catalogued as COSV53284661; called by muse, mutect2, varscan2
- KCNS2 | c.453C>A p.I151= | Silent (SNP) | VAF 46/521 reads (9%) | called by muse, mutect2
- KIAA1143 | c.270A>T p.P90= | Silent (SNP) | VAF 44/223 reads (20%) | called by muse, mutect2
- KIF1B | c.1653C>T p.I551= (on ENST00000377086 / NM_001365952.1; = p.I505= on NM_015074.3) | Silent (SNP) | VAF 20/472 reads (4%) | called by muse, mutect2
- KLC4 | c.444G>A p.E148= | Silent (SNP) | VAF 32/176 reads (18%) | called by muse, varscan2
- KMT2D | c.6948G>T p.L2316= | Silent (SNP) | VAF 35/219 reads (16%) | called by muse, mutect2, varscan2
- KRTAP4-8 | c.27G>C p.V9= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as COSV61565475; called by muse, mutect2, varscan2
- LEPR | c.1152G>T p.V384= | Silent (SNP) | VAF 79/526 reads (15%) | called by muse, mutect2, varscan2
- LGR6 | c.1449G>T p.G483= (on ENST00000367278 / NM_001017403.1; = p.G431= on NM_021636.3) | Silent (SNP) | VAF 55/233 reads (24%) | called by muse, mutect2, varscan2
- LILRB4 | c.309T>A p.P103= | Silent (SNP) | VAF 30/237 reads (13%) | called by muse, mutect2, varscan2
- LOXHD1 | c.5784C>T p.N1928= (on ENST00000642948; = p.N1866= on NM_144612.7) | Silent (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- LRRC4C | c.1155T>A p.S385= | Silent (SNP) | VAF 27/307 reads (9%) | called by muse, mutect2
- LTC4S | c.303G>A p.A101= | Silent (SNP) | VAF 26/418 reads (6%) | called by muse, mutect2
- LTK | c.1281G>T p.L427= | Silent (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2, varscan2
- MAP3K19 | c.1746C>T p.P582= | Silent (SNP) | VAF 63/278 reads (23%) | catalogued as rs1198847100; called by muse, mutect2, varscan2
- MAS1 | c.429T>C p.H143= | Silent (SNP) | VAF 41/405 reads (10%) | called by muse, mutect2, varscan2
- METTL15 | c.792C>T p.P264= | Silent (SNP) | VAF 34/140 reads (24%) | called by muse, varscan2
- MTUS2 | c.606C>A p.S202= | Silent (SNP) | VAF 32/243 reads (13%) | called by muse, mutect2, varscan2
- MUC16 | c.38703C>A p.G12901= | Silent (SNP) | VAF 46/267 reads (17%) | catalogued as COSV101199350; called by muse, mutect2, varscan2
- MUC17 | c.5835C>A p.T1945= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV60289392; called by muse, mutect2, varscan2
- MXRA5 | c.6702C>A p.L2234= | Silent (SNP) | VAF 12/259 reads (5%) | called by muse, mutect2
- NDFIP1 | c.45C>T p.C15= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs1482979680; called by muse, mutect2, varscan2
- NECTIN1 | c.1248G>T p.L416= | Silent (SNP) | VAF 141/406 reads (35%) | called by muse, varscan2
- NECTIN1 | c.888G>A p.Q296= | Silent (SNP) | VAF 49/434 reads (11%) | called by muse, mutect2, varscan2
- NFIC | c.810G>A p.T270= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as rs922657654; called by muse, mutect2
- NPY5R | c.507C>G p.A169= | Silent (SNP) | VAF 28/202 reads (14%) | catalogued as COSV58453272; called by muse, mutect2, varscan2
- NRG2 | c.981C>T p.Y327= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as rs748985660; called by muse, mutect2
- NRXN1 | c.186C>T p.S62= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs1186547259, COSV68048908; called by muse, mutect2, varscan2
- OBSCN | c.7839G>T p.T2613= | Silent (SNP) | VAF 125/460 reads (27%) | catalogued as rs752520625; called by muse, mutect2, varscan2
- OOEP | c.240G>T p.L80= | Silent (SNP) | VAF 55/172 reads (32%) | called by muse, mutect2, varscan2
- OR2W1 | c.405C>A p.V135= | Silent (SNP) | VAF 49/353 reads (14%) | catalogued as rs1275240200; called by muse, mutect2, varscan2
- OR52M1 | c.180C>T p.P60= | Silent (SNP) | VAF 35/240 reads (15%) | called by muse, mutect2, varscan2
- OR5AN1 | c.447C>A p.A149= | Silent (SNP) | VAF 13/196 reads (7%) | called by muse, mutect2
- OR5D18 | c.828T>C p.S276= | Silent (SNP) | VAF 31/295 reads (11%) | called by muse, mutect2, varscan2
- OR5F1 | c.580C>T p.L194= | Silent (SNP) | VAF 28/310 reads (9%) | catalogued as COSV53549115; called by muse, mutect2
- OR5I1 | c.570C>A p.S190= | Silent (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- OTOG | c.2070G>T p.L690= | Silent (SNP) | VAF 36/247 reads (15%) | called by muse, mutect2, varscan2
- P2RX6 | c.222C>A p.S74= | Silent (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- PALB2 | c.2064C>T p.N688= | Silent (SNP) | VAF 37/505 reads (7%) | called by muse, mutect2
- PAOX | c.645G>T p.P215= | Silent (SNP) | VAF 28/201 reads (14%) | called by muse, mutect2, varscan2
- PCBP3 | c.576G>A p.K192= | Silent (SNP) | VAF 29/275 reads (11%) | catalogued as rs767875882; called by muse, mutect2, varscan2
- PCDH11Y | c.2472A>T p.A824= (on ENST00000400457 / NM_032973.2; = p.A813= on NM_032971.3) | Silent (SNP) | VAF 123/322 reads (38%) | catalogued as COSV53085298; called by muse, mutect2, varscan2
- PCDHB11 | c.2013G>T p.L671= | Silent (SNP) | VAF 126/442 reads (29%) | called by muse, mutect2, varscan2
- PCSK6 | c.2634G>T p.V878= | Silent (SNP) | VAF 29/235 reads (12%) | catalogued as COSV61853740; called by muse, mutect2, varscan2
- PIK3R2 | c.744C>T p.A248= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, varscan2
- PPFIA2 | c.1977C>A p.A659= | Silent (SNP) | VAF 49/273 reads (18%) | called by muse, mutect2, varscan2
- PPP6R3 | c.2007G>T p.T669= (on ENST00000393800 / NM_001352375.2; = p.T589= on NM_018312.5) | Silent (SNP) | VAF 48/354 reads (14%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.1131C>A p.S377= | Silent (SNP) | VAF 142/688 reads (21%) | called by muse, mutect2, varscan2
- PRKACB | c.711C>T p.P237= | Silent (SNP) | VAF 26/243 reads (11%) | catalogued as rs755338285; called by muse, mutect2, varscan2
- PRPF8 | c.6351A>T p.I2117= | Silent (SNP) | VAF 35/425 reads (8%) | catalogued as rs746809986; called by muse, mutect2
- RAD18 | c.204A>C p.T68= | Silent (SNP) | VAF 33/162 reads (20%) | catalogued as COSV99368630; called by muse, mutect2, varscan2
- RAG1 | c.2130T>C p.Y710= | Silent (SNP) | VAF 42/222 reads (19%) | called by muse, varscan2
- RELN | c.603C>A p.I201= | Silent (SNP) | VAF 30/438 reads (7%) | catalogued as COSV59004734; called by muse, mutect2
- RHOH | c.78C>T p.S26= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as rs1398653997, COSV67806343; called by muse, mutect2, varscan2
- RPRM | c.126G>A p.A42= | Silent (SNP) | VAF 53/236 reads (22%) | catalogued as COSV57988751, COSV57988967; called by muse, mutect2, varscan2
- RUNDC3A | c.1018C>T p.L340= | Silent (SNP) | VAF 44/206 reads (21%) | called by muse, mutect2, varscan2
- RUSC2 | c.3486C>T p.P1162= | Silent (SNP) | VAF 50/131 reads (38%) | catalogued as rs753344319; called by muse, mutect2, varscan2
- SBNO1 | c.558A>T p.V186= (on ENST00000420886; = p.V185= on NM_018183.5) | Silent (SNP) | VAF 45/171 reads (26%) | called by muse, mutect2, varscan2
- SCN3A | c.5661T>A p.S1887= | Silent (SNP) | VAF 68/519 reads (13%) | called by muse, mutect2, varscan2
- SERPINA11 | c.375C>A p.T125= | Silent (SNP) | VAF 36/384 reads (9%) | called by muse, mutect2
- SERPINB11 | c.1053G>T p.G351= | Silent (SNP) | VAF 18/207 reads (9%) | catalogued as COSV66956800; called by muse, mutect2
- SLC22A23 | c.1629G>A p.V543= | Silent (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- SLC43A2 | c.690C>T p.P230= | Silent (SNP) | VAF 20/188 reads (11%) | called by muse, mutect2, varscan2
- SLC45A4 | c.1878C>T p.I626= (on ENST00000517878 / NM_001286646.2; = p.I575= on NM_001080431.2) | Silent (SNP) | VAF 40/668 reads (6%) | catalogued as rs1418560621, COSV50134125; called by muse, mutect2
- SPAST | c.633C>G p.V211= | Silent (SNP) | VAF 32/554 reads (6%) | called by muse, mutect2
- SPATA31A3 | c.2101T>C p.L701= | Silent (SNP) | VAF 102/815 reads (13%) | called by muse, mutect2, varscan2
- SYN3 | c.1626G>C p.L542= | Silent (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- TDRD9 | c.3172C>T p.L1058= | Silent (SNP) | VAF 93/351 reads (26%) | catalogued as rs1254237487; called by muse, mutect2, varscan2
- TFAP2D | c.1320G>A p.E440= | Silent (SNP) | VAF 42/376 reads (11%) | called by muse, varscan2
- TGIF2LX | c.33C>T p.T11= | Silent (SNP) | VAF 52/383 reads (14%) | called by muse, mutect2, varscan2
- TMEM244 | c.336C>T p.P112= | Silent (SNP) | VAF 24/298 reads (8%) | called by muse, mutect2
- TNR | c.2007C>A p.V669= | Silent (SNP) | VAF 20/311 reads (6%) | called by muse, mutect2
- TPTE | c.144A>T p.G48= | Silent (SNP) | VAF 30/515 reads (6%) | called by muse, mutect2
- TSC22D3 | c.285C>A p.T95= | Silent (SNP) | VAF 150/244 reads (61%) | called by muse, mutect2, varscan2
- UGP2 | c.312G>T p.V104= | Silent (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- USH2A | c.843A>T p.T281= | Silent (SNP) | VAF 49/426 reads (12%) | called by muse, mutect2, varscan2
- VPS13C | c.4363C>T p.L1455= (on ENST00000644861 / NM_020821.3; = p.L1412= on NM_017684.5) | Silent (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- VWC2 | c.588C>T p.H196= | Silent (SNP) | VAF 70/325 reads (22%) | catalogued as rs375117513; called by muse, mutect2, varscan2
- WASHC2C | c.2952A>T p.P984= (on ENST00000336378; = p.P963= on NM_015262.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 45/423 reads (11%) | called by muse, mutect2, varscan2
- WNT9B | c.243T>A p.A81= | Silent (SNP) | VAF 21/186 reads (11%) | called by muse, mutect2, varscan2
- WSCD1 | c.1563G>A p.E521= | Silent (SNP) | VAF 48/345 reads (14%) | catalogued as rs1555529535; called by muse, mutect2, varscan2
- ZAR1L | c.381G>T p.L127= | Silent (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- ZNF331 | c.675G>T p.R225= | Silent (SNP) | VAF 26/204 reads (13%) | called by muse, mutect2, varscan2
- ZNF804B | c.726A>T p.T242= | Silent (SNP) | VAF 18/302 reads (6%) | called by muse, mutect2
- ADGRL4 | c.22+42A>T | Intron (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- AHSG | c.-17G>A | 5'UTR (SNP) | VAF 84/344 reads (24%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825190 del A | 5'Flank (DEL) | VAF 44/352 reads (13%) | called by mutect2, pindel, varscan2
- AL353804.7 | chrX:73851479 A>G | 3'Flank (SNP) | VAF 64/419 reads (15%) | called by muse, mutect2, varscan2
- ALOX12B | c.434+34G>A | Intron (SNP) | VAF 22/351 reads (6%) | catalogued as rs765763108; called by muse, mutect2
- ANKRD18A | chr9:38622016 G>A | 5'Flank (SNP) | VAF 37/111 reads (33%) | catalogued as rs901339750; called by muse, mutect2, varscan2
- ANO1 | c.2198-794G>T | Intron (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- APBA2 | c.2037+44G>T | Intron (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2
- C4A | chr6:32006311 G>T | 3'Flank (SNP) | VAF 80/175 reads (46%) | called by muse, mutect2, varscan2
- CATSPER2 | c.-86-33G>C | Intron (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- CCDC159 | c.22-16C>T | Intron (SNP) | VAF 20/264 reads (8%) | called by muse, mutect2
- CCDC73 | c.429+50G>T | Intron (SNP) | VAF 32/257 reads (12%) | called by muse, mutect2, varscan2
- CCDC74A | c.251-91G>C | Intron (SNP) | VAF 38/222 reads (17%) | called by muse, mutect2, varscan2
- CCNT2 | c.494-271T>C | Intron (SNP) | VAF 44/208 reads (21%) | called by muse, varscan2
- CDH13 | c.-10G>A | 5'UTR (SNP) | VAF 57/498 reads (11%) | called by muse, mutect2, varscan2
- CEP44 | c.*15A>T | 3'UTR (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- COL21A1 | c.1543-17T>G | Intron (SNP) | VAF 91/326 reads (28%) | called by muse, mutect2, varscan2
- CYP4F24P | n.440G>T | RNA (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- D2HGDH | c.*32G>T | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by mutect2, varscan2
- DST | c.4297-1241A>C | Intron (SNP) | VAF 42/514 reads (8%) | called by muse, mutect2
- DYRK2 | c.198+1586G>T | Intron (SNP) | VAF 44/206 reads (21%) | called by muse, mutect2, varscan2
- ECHDC1 | c.435-192T>A | Intron (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- EIF3G | c.-14G>T | 5'UTR (SNP) | VAF 39/317 reads (12%) | catalogued as rs1330257100; called by muse, mutect2, varscan2
- EPOR | c.*7A>T | 3'UTR (SNP) | VAF 38/428 reads (9%) | called by muse, mutect2
- FCRL5 | c.1681+296T>G | Intron (SNP) | VAF 16/231 reads (7%) | called by muse, mutect2
- GABRG2 | c.1042+38A>T | Intron (SNP) | VAF 125/454 reads (28%) | called by muse, mutect2, varscan2
- GPBP1 | c.478+1141G>T | Intron (SNP) | VAF 175/418 reads (42%) | called by muse, mutect2, varscan2
- GUCA1A | c.202-9C>A | Intron (SNP) | VAF 56/419 reads (13%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.518A>C | RNA (SNP) | VAF 17/142 reads (12%) | called by muse, mutect2, varscan2
- IGSF21 | c.*7C>A | 3'UTR (SNP) | VAF 28/175 reads (16%) | called by muse, varscan2
- KANSL1 | c.-89-24179T>C | Intron (SNP) | VAF 59/254 reads (23%) | called by muse, mutect2, varscan2
- L1CAM | chrX:153887005 C>T | 5'Flank (SNP) | VAF 51/274 reads (19%) | called by muse, mutect2, varscan2
- LILRB5 | c.1630-137G>T | Intron (SNP) | VAF 39/237 reads (16%) | called by muse, mutect2, varscan2
- LINC00840 | n.301G>T | RNA (SNP) | VAF 76/344 reads (22%) | called by muse, mutect2, varscan2
- LVRN | c.*51C>T | 3'UTR (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- MAN1B1 | c.*416C>A | 3'UTR (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- MED13L | c.3935-40G>T | Intron (SNP) | VAF 53/254 reads (21%) | called by muse, mutect2, varscan2
- MICAL2 | c.3334+32G>T | Intron (SNP) | VAF 40/172 reads (23%) | called by muse, mutect2, varscan2
- MUC19 | n.5790G>C | RNA (SNP) | VAF 61/278 reads (22%) | called by muse, mutect2, varscan2
- NDUFB10 | chr16:1965152 C>T | 3'Flank (SNP) | VAF 38/169 reads (22%) | catalogued as rs767119920; called by muse, mutect2, varscan2
- NOC4L | c.345+596A>G | Intron (SNP) | VAF 28/255 reads (11%) | catalogued as rs928416935; called by muse, mutect2, varscan2
- OR2P1P | chr6:29076378 G>T | 5'Flank (SNP) | VAF 16/240 reads (7%) | called by muse, mutect2
- PCMTD1 | c.-272G>T | 5'UTR (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- PHLDB3 | c.825+21G>C | Intron (SNP) | VAF 5/28 reads (18%) | called by mutect2, varscan2
- PLPBP | chr8:37784257 C>A | 3'Flank (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- PMM2 | c.347+42G>T | Intron (SNP) | VAF 73/382 reads (19%) | catalogued as rs374076809; called by muse, mutect2, varscan2
- POLR2D | c.-9G>T | 5'UTR (SNP) | VAF 25/164 reads (15%) | called by muse, mutect2, varscan2
- PSG6 | c.-4G>T | 5'UTR (SNP) | VAF 20/185 reads (11%) | called by muse, varscan2
- RBMX | c.110-83C>A | Intron (SNP) | VAF 45/294 reads (15%) | called by muse, mutect2, varscan2
- RGMB | chr5:98770666 A>G | 5'Flank (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159049 G>T | 5'Flank (SNP) | VAF 64/302 reads (21%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1900G>A | RNA (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- RNU1-5P | chr1:16871800 C>A | 5'Flank (SNP) | VAF 38/397 reads (10%) | called by muse, mutect2
- SAA2 | chr11:18242812 A>T | 3'Flank (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- SDHAP1 | n.2275C>T | RNA (SNP) | VAF 58/561 reads (10%) | called by muse, mutect2, varscan2
- SH3TC2 | c.280-1302G>T | Intron (SNP) | VAF 15/56 reads (27%) | catalogued as rs928215694; called by muse, mutect2, varscan2
- SHANK2 | c.1108-56201G>T | Intron (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- SLC17A3 | c.304-249C>A | Intron (SNP) | VAF 26/224 reads (12%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.523-98G>T | Intron (SNP) | VAF 46/417 reads (11%) | catalogued as rs759150361; called by muse, mutect2, varscan2
- SYTL2 | c.1459+3449A>C | Intron (SNP) | VAF 12/132 reads (9%) | catalogued as COSV60356570; called by muse, mutect2
- TCL1B | c.*3C>A | 3'UTR (SNP) | VAF 12/165 reads (7%) | called by muse, mutect2
- TTC21B | c.1386+62A>G | Intron (SNP) | VAF 37/239 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10360+4999G>A | Intron (SNP) | VAF 74/635 reads (12%) | called by muse, mutect2, varscan2
- UQCRB | c.*684G>T | 3'UTR (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- VAPB | c.*2630G>T | 3'UTR (SNP) | VAF 35/197 reads (18%) | called by muse, mutect2, varscan2
- WDR6 | c.101-165G>T | Intron (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- ZC4H2 | c.399-50G>T | Intron (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-1546-30624C>A | Intron (SNP) | VAF 46/122 reads (38%) | called by muse, varscan2
- ZNF714 | c.*766G>A | 3'UTR (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
